Gene-level copy-number profile of tumor specimen TCGA-CG-5727-01A from TCGA case TCGA-CG-5727, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.5 years (24,289 days).
Specimen TCGA-CG-5727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b9eb243f-8f72-49e0-a372-3f88948caf5a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5727-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7ba2f5f-61f7-40eb-a3b6-410d5350ad72

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 18; copy number 2: 7,166; copy number 3: 36,538; copy number 4: 8,780; copy number 5: 1,160; copy number 6: 1,136; copy number 7: 1,226; copy number 8: 70; copy number 9: 2,975; copy number 10: 261; copy number 11: 418; copy number 12: 3; copy number 13: 15; copy number 19: 21; copy number 23: 25; copy number 24: 3; copy number 29: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5727-01A-11D-1599-01): tumor purity 0.49, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,020 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:106,933,739–106,996,534, 3 genes, copy number 11 (within-gene range 6–11): AC005040.2, PPP1R2P5, AC005040.1.
- chr2:108,719,482–135,176,394, 517 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).
- chr4:142,023,160–142,847,432, 3 genes, copy number 7–19 (within-gene range 2–19): INPP4B, RPL5P13, LSM3P4.
- chr4:144,109,303–144,870,953, 2 genes, copy number 13 (within-gene range 2–31): GYPA, AC098588.3.
- chr6:43,629,540–44,265,788, 25 genes, copy number 23 (within-gene range 3–23): MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE.
- chr7:57,270,839–57,777,521, 22 genes, copy number 7: AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2.
- chr7:83,955,777–109,999,624, 509 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 1 gene, copy number 9 (within-gene range 0–9): IMMP2L.
- chr7:111,091,006–143,523,449, 648 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr7:148,389,645–159,233,377, 243 genes, copy number 7–9 (broad region; genes not listed).
- chr8:43,442,902–145,066,685, 1,543 genes, copy number 8–11 (broad region; genes not listed).
- chr11:85,694,224–86,423,109, 17 genes, copy number 19 (within-gene range 4–19): SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81.
- chr11:86,432,098–86,437,282, 2 genes, copy number 19: PTP4A1P6, AP001148.1.
- chr13:27,792,483–28,295,335, 16 genes, copy number 13–29: GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P.
- chr13:30,456,704–30,810,645, 9 genes, copy number 10: HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398.
- chr13:30,932,656–31,437,999, 9 genes, copy number 11–24 (within-gene range 2–24): TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2.
- chr20:87,250–16,053,197, 288 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
